Surgical pathology report (de-identified scan), TCGA case TCGA-WB-A81S, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Erasmus MC, specimen TCGA-WB-A81S-01A (Primary Tumor).

Unique Patient Identifier:

Short descriptive translation of the pathology report as provided by the

Date report:

Material received:

Material: right adrenal

Macroscopic findings:

within the adrenal tumor with white, partly reddish appearance (6.5x4.7 cm in size) Minimal margin of the normal adrenal: 2mm.

Microscopic findings:

cells of different size with eosinophilic, fine granular cytoplasm with differently shaped nuclei. Partly bizarre hyperchromatic nuclei. No necrosis, no atypical mitosis. Immunopositivity for chromogranin A, synaptophysin, protein100. Ki67 index maximal 1%. No nuclear staining for p53.

Conclusion:

Pheochromocytoma of the right adrenal

Translated by:

ICD-O-3
Pheochromocytoma NOS
8700/0
Site: (R) Adrenal gland NOS
C74.9
JW 10/17/13

Source: NCI Genomic Data Commons file af4adc64-6b43-474c-b964-7d70423eeed8 (TCGA-WB-A81S.32D87FE7-114E-49FA-9A71-724F6F29BD5A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).